Surgical pathology report (de-identified scan), TCGA case TCGA-21-1076, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1076-01A (Primary Tumor).

[page 1 of 4]
Clinical History/Diagnosis: Left Lung Cancer.

Source of Specimen(s):

A: Portion of 5th Rib
B: Portion of 6th Rib
C: Portion of 7th Rib
D: Portion of 8th Rib
E: Level 9 Lymph Nodes
F: Lymph Node, level 11
G: Level 5 Lymph Nodes
H: Level 10 Lymph Node
I: Left lung

Gross Description:

Received in nine parts.

Source of Tissue: 1. Labeled #1, "portion of 5th rib"

Gross Description: Received fresh with patient name and medical record number labeled "portion of 5th rib". It consists of a jagged fragment of rib measuring 1.5 x 1.0 x 0.9 cm. No suspicious lesions or masses are identified. Submitted entirely in 1A, following decalcification.

*

Source of Tissue: 2. Labeled #2, "portion of 6th rib"

Gross Description: Received fresh with patient name and medical record number labeled "portion of 6th rib". It consists of a fragment of rib measuring 1.5 x 0.8 x 0.7 cm. No lesions or masses are identified. Submitted entirely in 2A.

*

Source of Tissue: 3. Labeled #3, "portion of 7th rib"

Gross Description: Received fresh with patient name and medical record number labeled "portion of 7th rib". It consists of a jagged fragment of rib measuring 1.5 x 0.9 x 0.8 cm. No suspicious lesions or masses are identified. Submitted entirely in 3A.

*

Source of Tissue: 4. Labeled #4, "portion of left 8th rib"

[page 2 of 4]
Gross Description: Received fresh with patient name and medical record number labeled "portion of left 8th rib". It consists of a fragment of rib measuring 2 x 0.7 x 0.7 cm. No suspicious lesions or masses are identified. Submitted entirely in 4A.

*

Source of Tissue: 5. Labeled #5, "level 9 lymph nodes"

Gross Description: Received fresh with patient name and medical record number labeled "level 9 lymph nodes". It consists of two grayish-black lymph nodes measuring 0.5 and 1.0 cm respectively. Submitted in toto in 5A.

*

Source of Tissue: 6. Labeled #6, "level 11 lymph node"

Frozen Section Diagnosis: 6FS- NO METASTATIC CARCINOMA.

Gross Description: Received fresh for frozen section evaluation with patient name and medical record number labeled "level 11 lymph node". It consists of a single brownish-red lymph node measuring 1.1 x 1.0 x 0.9 cm. It is bisected disclosing a brown glistening cut surface. Entirely submitted for frozen section and the residue is submitted in 6FS.

Source of Tissue: 7. Labeled #7, "level 5 lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "level 5 lymph node". It consists of a single dark-red nodule measuring 0.6 x 0.4 x 0.4 cm. Submitted entirely in 7A.

Source of Tissue: 8. Labeled #8, "level 10 lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "level 10 lymph node". It consists of three dark-red nodules measuring respectively 0.5, 0.6 and 0.9 cm in greatest dimension. Submitted in toto in 8A.

Source of Tissue: 9. Labeled #9, "left lung"

Frozen Section Diagnosis: 9FS- BRONCHIAL MARGIN WITH NO TUMOR SEEN.

Gross Description: Received fresh for frozen section evaluation with patient name and medical record number labeled "left lung". It consists of a 481 gram right lung specimen with an overall measurement of 24 x 13 x 6.5 cm. The lower lobe measures 14 x 10 x 6 cm and the upper lobe measures approximately 15 x 10 x 6 cm. The bronchial margin is

[page 3 of 4]
unremarkable. The bronchial margin was procured for frozen section consultation and the residue is submitted in 9FS. The diaphragmatic surface is normal appearing. Multiple bronchial and peribronchial lymph nodes are found measuring up to 2 cm and a few are tan and firm. Vascular margins are unremarkable. On dissection through the hilum, tumor comes to within 1.4 cm from the margin and closely approaches an airway and vessel (E and F). Sections disclose a 8 x 8 x 6 cm tumor in the left lower lobe. Tumor grossly is adhered to the upper lobe (9J). Tumor is adhered to the costal soft tissue with rib and associated soft tissue measuring 10.5 x 9 x 1.4 cm. Sections show no gross invasion into the costal resection. Tumor is tan and approximately 80% is necrotic. Elsewhere the lower lobe is pink and spongy while the upper lobe is predominantly red and dense.

Designation of Sections: 9A- vascular margin, 9B-9D- hilar and peribronchial lymph nodes, 9E-9F- tumor approaching hilum, 9G- tumor with pleura, 9H- tumor in relationship to adjacent lung tissue, 9I- tumor in relationship to costal soft tissue, 9J- tumor in relationship to left upper lobe adhesion, 9K- uninvolved lower and upper lobes, 9L- costal resection/ribs, following decalcification.

Final Diagnosis:

1. 5th rib (resection):
- Unremarkable rib. Hypercellular marrow.
2. 6th rib (resection):
- Unremarkable rib. Hypercellular marrow.
3. 7th rib (resection):
- Unremarkable rib. Hypercellular marrow.
4. 8th rib (resection):
- Unremarkable rib. Hypercellular marrow.
5. Lymph nodes, level 9 (excision):
- Two lymph nodes negative for metastatic carcinoma (0/2).
6. Lymph node, level 11 (excision):
- One lymph node negative for metastatic carcinoma (0/1).
7. Lymph node, level 5 (excision):
- One lymph node negative for metastatic carcinoma (0/1).
8. Lymph nodes, level 10 (excision):
- Two lymph nodes negative for metastatic carcinoma (0/2).
9. Lung, left (left pneumonectomy):
- Squamous cell carcinoma, moderate to poorly differentiated (8.0 cm).
- The visceral pleura is negative for tumor.
- The bronchial, vascular and costal resection margins are free of tumor.

[page 4 of 4]
- Sixteen peribronchial lymph nodes are negative for metastatic carcinoma (0/16).
- Emphysematous changes.
- Chronic inflammation with fibrous adhesions to chest wall.
- pT2N0Mx.

Source: NCI Genomic Data Commons file a4b9d2dc-ac19-42aa-be21-362c88370933 (TCGA-21-1076.990CC93F-4AF3-4AF5-8CD7-0BB81133E1BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).